Somatic mutation profile of tumor specimen 0DYRPX from CCDI case PBCSSD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.4 years (1,962 days).
Specimen 0DYRPX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d2c450d-66cd-436e-8592-93e0db69718e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DYRPU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8f0f0c9-32e0-4f18-89ce-3b367384d996

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.787A>C p.T263P | Missense Mutation (SNP) | VAF 124/692 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.236); catalogued as rs1057519829, COSV51768130; ClinVar: likely pathogenic; called by muse, varscan2
- SYT7 | c.967G>A p.V323M | Missense Mutation (SNP) | VAF 94/922 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.371); called by muse, varscan2
- CACNA2D1 | c.268C>T p.L90= | Silent (SNP) | VAF 61/634 reads (10%) | called by muse, varscan2
- ALG13 | c.-5G>A | 5'UTR (SNP) | VAF 43/428 reads (10%) | called by muse, varscan2
- GOLGA6L3 | n.876A>G | RNA (SNP) | VAF 5/72 reads (7%) | catalogued as rs1425269449; called by muse, varscan2
